Surgical pathology report (de-identified scan), TCGA case TCGA-TM-A7CA, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site The University of New South Wales, specimen TCGA-TM-A7CA-01A (Primary Tumor).

CLINICAL:

Right insular tumour, ? low grade glioma.

MACROSCOPIC:

Specimen labelled "Brain tumour", consists of fragments of brain tissue from 1-5mm. AE 1 block.

MICROSCOPIC: (Reported by

The sections of cerebral tissue show focal areas of mild to moderately hypercellular glial tissue associated with mild nuclear atypia and scattered microgemistocytes. Some of the atypical glial cells have round nuclei and there is a network of branching capillaries, however, the overall features fall short of a definite diagnosis of oligodendroglioma. Mitoses are not seen and there is no necrosis.

Ki67 staining shows positive staining of approximately 2% of nuclei within areas of tumour.

I have reviewed this case with Dr [redacted] and we agree that the overall features are consistent with a low grade astrocytoma (grade 2, WHO). In view of the presence of some suggestive features of oligodendroglioma, consideration may be given to further genetic testing on this tumour (1p/19q deletion).

Staining for IDH1 is also in progress.

A copy of this report has been faxed to

DIAGNOSIS:

MAIN: LOW GRADE ASTROCYTOMA (WHO GRADE 2) - SEE ABOVE.

Last edited :

ICD-O-3
Astrocytoma, grade II 9400/3
Site Brain, supratentorial NOS C71.0
path
@ Brain, insula C71.0
JW 9/25/13

Source: NCI Genomic Data Commons file a8f65cab-9478-429f-b9d3-8731475cc14e (TCGA-TM-A7CA.FA7FFEBC-9D1C-42E6-BD8E-BB957EE8C870.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).